Gene-level copy-number profile of tumor specimen TCGA-2G-AAGJ-01A from TCGA case TCGA-2G-AAGJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 28.3 years (10,348 days).
Specimen TCGA-2G-AAGJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.2a6dc3ef-ce08-4c17-ac94-bbdb9b727d7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/25db72fa-0d92-4b05-ac05-8f4d0d780f37

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 132; copy number 2: 19,377; copy number 3: 28,166; copy number 4: 4,476; copy number 5: 4,837; copy number 6: 1,053; copy number 7: 1,773.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGJ-01A-11D-A42X-01): tumor purity 0.41, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,773 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:60,914,407–117,415,070, 962 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:66,767–32,107,528, 810 genes, copy number 7 (broad region; genes not listed).
- chr12:32,109,076–32,109,602, 1 gene, copy number 7: AC048344.4.

Autosomal genes at a single copy (total copy number 1): 130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
